Surgical pathology report (de-identified scan), TCGA case TCGA-BR-A4CQ, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-A4CQ-01A (Primary Tumor).

Gross Description: Stomach size is 20*9 cm with entree form tumor 4*4 cm, colour is white-haired, compact. ?mentum is yellow and soft.

Microscopic Description: 1) Little differential adenocarcinoma p13.

2) In 2 Lymph nodes- metastases ?? carcinoma.

Diagnosis Details: Tumor Features: -1, Tumor Extent: Head of polyp , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Cardia

Tumor size: 4 x 0 x 4 cm

Tumor features: None specified

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 2/3 positive for metastasis (Regional 2/3)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
adenocarcinoma, NOS 8140/3
site: stomach, cardia, NOS C16.0
JW
9/27/12

1PAA Discrepancy		X
Reviewed: Initial	Date Reviewed: 8/31/12	

JW 9/27/12

Source: NCI Genomic Data Commons file fa43ec33-41ef-48fa-9d73-d96d9040d06b (TCGA-BR-A4CQ.D748B3EE-B773-4B33-85D3-6BDAB268C7BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).